Somatic mutation profile of tumor specimen TCGA-31-1959-01A (aliquot TCGA-31-1959-01A-01W-0699-08) from TCGA case TCGA-31-1959, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 50.0 years (18,247 days).
Specimen TCGA-31-1959-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca8b033f-d827-4d9e-bc8f-35afc3466bcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-31-1959-10A (Blood Derived Normal), aliquot TCGA-31-1959-10A-01W-0700-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af42d78c-0552-40b5-9086-d788301ca628

The open-access MAF lists 76 somatic variants for this specimen: 53 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 19, 5'UTR 2, Frame Shift Del 2, Splice Site 2, In Frame Del 1, 3'UTR 1, Translation Start Site 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 154/420 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.4223T>A p.F1408Y | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV55587503; called by muse, mutect2, varscan2
- ADGRB1 | c.2312T>C p.L771P | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60092321; called by muse, mutect2, varscan2
- ALDH1L1 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV56411067; called by muse, mutect2, varscan2
- BCLAF1 | c.1862T>A p.F621Y | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1222959651, COSV99219826; called by muse, mutect2, varscan2
- C9orf50 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV100992349; called by muse, varscan2
- CA4 | c.793A>G p.S265G | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV56280931; called by muse, varscan2
- CAD | c.2270G>T p.S757I | Missense Mutation (SNP) | VAF 16/425 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV99255630; called by muse, mutect2
- CCDC158 | c.2125G>C p.E709Q | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV66355259; called by muse, mutect2, varscan2
- CCDC178 | c.402A>C p.K134N | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV55760935; called by muse, mutect2, varscan2
- CGRRF1 | c.778T>C p.S260P | Missense Mutation (SNP) | VAF 93/241 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV53595652; called by muse, mutect2, varscan2
- CLPB | c.29A>G p.K10R | Missense Mutation (SNP) | VAF 82/119 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV53627620; called by muse, mutect2, varscan2
- CTNNA1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 26/74 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as COSV57069995; called by muse, mutect2, varscan2
- CTNND2 | c.1641G>C p.W547C | Missense Mutation (SNP) | VAF 75/322 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58867881; called by muse, mutect2, varscan2
- DAPP1 | c.345T>G p.I115M | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV99597216; called by muse, mutect2
- GSPT1 | c.557G>A p.R186K (on ENST00000420576 / NM_001130007.2; = p.R324K on NM_002094.4) | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV70452455; called by muse, varscan2
- LILRA5 | c.469A>G p.N157D | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV56641596; called by muse, mutect2, varscan2
- MAP4K3 | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1208935569, COSV55710270; called by muse, mutect2
- MEAK7 | c.900C>A p.D300E | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV100640453; called by muse, mutect2
- MED11 | c.196C>A p.Q66K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV53411152; called by muse, mutect2, varscan2
- MEF2D | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV100560314; called by muse, mutect2
- MYH7B | c.4261A>C p.S1421R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV52677221; called by muse, mutect2, varscan2
- MYO16 | c.806A>T p.N269I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV99194540; called by muse, varscan2
- MYO16 | c.807T>A p.N269K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as COSV99194547; called by muse, varscan2
- NCBP2L | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 142/385 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100966525; called by muse, mutect2, varscan2
- NDN | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV59358542; called by muse, mutect2
- NPC1L1 | c.4011C>G p.S1337R | Missense Mutation (SNP) | VAF 119/347 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV56922766; called by muse, mutect2, varscan2
- PRC1 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 159/374 reads (43%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.917); catalogued as COSV62694244, COSV62694509; called by muse, mutect2, varscan2
- PROKR2 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.317); catalogued as rs576243101, COSV54085395; called by muse, mutect2, varscan2
- ROBO3 | c.3428C>T p.S1143F | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100127848, COSV100127915, COSV60621453; called by muse, mutect2
- RSPH6A | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV99679769; called by muse, mutect2, varscan2
- RSPH6A | c.438G>T p.L146F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV99680086; called by muse, mutect2, varscan2
- SCN3A | c.1576T>C p.S526P | Missense Mutation (SNP) | VAF 131/534 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51802393; called by muse, mutect2, varscan2
- SLC36A1 | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 291/675 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.371); catalogued as COSV99695736; called by muse, mutect2, varscan2
- SLC4A11 | c.1507G>C p.V503L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV66260628; called by muse, mutect2, varscan2
- SMAD7 | c.1276C>G p.R426G | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.695); catalogued as COSV100053055, COSV50989562; called by muse, mutect2, varscan2
- SNED1 | c.4073C>T p.S1358F | Missense Mutation (SNP) | VAF 204/734 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54088005; called by muse, mutect2, varscan2
- SPTBN2 | c.3679C>T p.R1227W | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs766811381, COSV59447657; called by muse, mutect2, varscan2
- SYNM | c.4340C>G p.T1447R | Missense Mutation (SNP) | VAF 200/909 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV50440761, COSV50443415; called by muse, mutect2, varscan2
- TRPM2 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55966434; called by muse, mutect2, varscan2
- TRPS1 | c.406C>T p.P136S (on ENST00000220888 / NM_001330599.2; = p.P149S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/179 reads (51%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.015); catalogued as rs1443603275, COSV55227965; called by muse, mutect2, varscan2
- TTL | c.272G>T p.C91F | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV51973292; called by muse, mutect2, varscan2
- USP51 | c.1054A>G p.R352G | Missense Mutation (SNP) | VAF 121/485 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV72351496; called by muse, mutect2, varscan2
- UTP14A | c.2315G>C p.*772Sext*21 | Nonstop Mutation (SNP) | VAF 85/301 reads (28%) | catalogued as COSV64086332; called by muse, mutect2, varscan2
- WWC3 | c.1688C>A p.S563Y | Missense Mutation (SNP) | VAF 37/1112 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101081739; called by muse, mutect2
- ZGRF1 | c.2083C>G p.Q695E | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.96); PolyPhen benign (0.009); catalogued as COSV52199089; called by muse, mutect2, varscan2
- ZNF770 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); catalogued as COSV100696047; called by muse, mutect2
- ZNF91 | c.635G>A p.C212Y | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as rs748461896, COSV100322955, COSV56081004, COSV56095107; called by muse, mutect2, varscan2
- ABCF2 | c.1507_1523del p.Y503Tfs*34 | Frame Shift Del (DEL) | VAF 74/461 reads (16%) | called by mutect2, pindel, varscan2
- ERICH3 | c.2731_2751del p.L911_H917del | In Frame Del (DEL) | VAF 105/967 reads (11%) | called by mutect2, pindel
- GARNL3 | c.533del p.G178Afs*24 | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- NF1 | c.6922-2_6967del p.X2308_splice (on ENST00000358273 / NM_001042492.3; = p.X2287_splice on NM_000267.3) | Splice Site (DEL) | VAF 16/151 reads (11%) | called by mutect2, pindel
- TEKT1 | c.853-8_867del p.X285_splice | Splice Site (DEL) | VAF 57/278 reads (21%) | called by mutect2, pindel
- ABCC10 | c.2004G>A p.L668= (on ENST00000372530 / NM_001198934.2; = p.L640= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as COSV55084829; called by muse, mutect2, varscan2
- ADCY2 | c.3210C>T p.D1070= | Silent (SNP) | VAF 72/292 reads (25%) | catalogued as rs1198524822, COSV57860210; called by muse, mutect2, varscan2
- C2orf66 | c.192C>T p.F64= | Silent (SNP) | VAF 74/362 reads (20%) | catalogued as COSV61098515; called by muse, mutect2, varscan2
- C9orf50 | c.1020C>T p.S340= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs1258119013, COSV100992348; called by muse, varscan2
- CCDC73 | c.795G>A p.K265= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100068270; called by muse, mutect2, varscan2
- CFAP46 | c.7485C>A p.V2495= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV99585479; called by muse, mutect2, varscan2
- CTBS | c.237A>G p.T79= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV55361289; called by muse, mutect2, varscan2
- DAOA | c.225G>A p.R75= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV100298897; called by muse, mutect2
- DGKI | c.1344G>T p.L448= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV55937817; called by muse, mutect2, varscan2
- ETV4 | c.1194G>C p.S398= | Silent (SNP) | VAF 124/313 reads (40%) | catalogued as COSV52251139; called by muse, mutect2, varscan2
- FBN2 | c.1989G>A p.Q663= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs770141524, COSV52494868, COSV99330491; called by muse, mutect2, varscan2
- H2BC11 | c.78C>T p.D26= | Silent (SNP) | VAF 93/321 reads (29%) | catalogued as rs138662108, COSV60361747; called by muse, mutect2, varscan2
- KRT34 | c.936G>T p.A312= | Silent (SNP) | VAF 13/340 reads (4%) | called by muse, mutect2
- SHKBP1 | c.1500C>T p.Y500= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs373280102; called by muse, mutect2, varscan2
- SSTR4 | c.504G>T p.L168= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99658786; called by muse, mutect2, varscan2
- TMEM241 | c.858C>A p.A286= | Silent (SNP) | VAF 54/223 reads (24%) | catalogued as COSV67243157; called by muse, mutect2, varscan2
- TRPV3 | c.54C>G p.A18= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV56788973; called by muse, mutect2, varscan2
- VPS13C | c.8916G>A p.E2972= (on ENST00000644861 / NM_020821.3; = p.E2929= on NM_017684.5) | Silent (SNP) | VAF 66/141 reads (47%) | catalogued as rs1278128548, COSV51124201; called by muse, mutect2, varscan2
- ZNF821 | c.759C>A p.P253= (on ENST00000425432 / NM_001376297.1; = p.P211= on NM_017530.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 118/329 reads (36%) | catalogued as COSV57986867; called by muse, mutect2, varscan2
- ELAVL2 | c.-12-2824G>C | Intron (SNP) | VAF 98/296 reads (33%) | catalogued as COSV99805418, COSV99807114; called by muse, mutect2, varscan2
- EPDR1 | c.-124A>C | 5'UTR (SNP) | VAF 12/56 reads (21%) | catalogued as COSV52258383; called by muse, mutect2, varscan2
- FGFR3 | c.*801G>T | 3'UTR (SNP) | VAF 16/30 reads (53%) | catalogued as COSV53392938; called by muse, varscan2
- SKA1 | c.-1G>A | 5'UTR (SNP) | VAF 30/78 reads (38%) | catalogued as rs1454437505, COSV99552906; called by muse, mutect2, varscan2
